Gene-level copy-number profile of tumor specimen TCGA-O1-A52J-01A from TCGA case TCGA-O1-A52J, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.5 years (27,223 days).
Specimen TCGA-O1-A52J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9e6f75ae-0ffd-46a6-833f-36d226655ef6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-O1-A52J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d6c5e83-4b34-4bb1-bf7d-6d21e00d9191

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 451; copy number 2: 16,304; copy number 3: 10,237; copy number 4: 19,845; copy number 5: 6,744; copy number 6: 3,463; copy number 7: 205; copy number 8: 2,416; copy number 9: 135; copy number 10: 8; copy number 11: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-O1-A52J-01A-11D-A25M-01): tumor purity 0.5, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 143 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,819,727–38,154,624, 4 genes, copy number 10 (within-gene range 5–10): ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr12:56,416,363–58,395,138, 98 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:64,255,695–64,313,132, 4 genes, copy number 10 (within-gene range 6–10): PCMTD2, AL137028.2, CICP4, LINC00266-1.
- chr21:27,638,613–27,751,233, 2 genes, copy number 9: LINC01673, LINC00113.
- chr21:45,405,165–45,513,720, 1 gene, copy number 9 (within-gene range 4–9): COL18A1.
- chr21:45,478,266–46,445,769, 34 genes, copy number 9: MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2.

Autosomal genes at a single copy (total copy number 1): 451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
